Somatic mutation profile of cancer-model specimen HCM-WCMC-0673-C56-85A (3D Organoid, passage 11; aliquot HCM-WCMC-0673-C56-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db0c398d-0dd8-4e7a-9000-5d18af515877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0673-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-0673-C56-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2bfe2c8-b9bc-463b-b24b-2bf880b4f7c6

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 3, Frame Shift Del 2, Nonstop Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 130/276 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 127/127 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.869del p.R290Pfs*55 | Frame Shift Del (DEL) | VAF 245/340 reads (72%) | hotspot (GDC flag); catalogued as CM065493, CM993905, COSV52683585, COSV53296796; called by mutect2, pindel, varscan2
- ADAM22 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368940210; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 131/384 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749681357, COSV58441412; called by muse, mutect2, varscan2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2, varscan2
- METTL8 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 132/301 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754629409; called by muse, mutect2, varscan2
- OR10K2 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 122/333 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV59222347, COSV59223040; called by muse, mutect2, varscan2
- SLK | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59826566; called by muse, mutect2, varscan2
- STARD9 | c.9842C>T p.P3281L | Missense Mutation (SNP) | VAF 172/414 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs1377609704; called by muse, varscan2
- ULK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 199/419 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1018512142; called by muse, varscan2
- ZNF681 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV68074534; called by muse, varscan2
- ABCC2 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANKRD33B | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 328/679 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, varscan2
- ATP1A2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 120/259 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CACNA1G | c.6833G>C p.G2278A | Missense Mutation (SNP) | VAF 25/693 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); called by muse, mutect2
- CDKN2A | c.263_264del p.E88Gfs*31 | Frame Shift Del (DEL) | VAF 383/521 reads (74%) | called by mutect2, pindel, varscan2
- KATNA1 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 19/561 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- KDM4D | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 196/468 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, varscan2
- KLHL34 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.192); called by muse, mutect2
- LARS1 | c.1284+1G>T p.X428_splice (on ENST00000394434 / NM_020117.11; = p.X401_splice on NM_016460.3) | Splice Site (SNP) | VAF 77/172 reads (45%) | called by muse, mutect2, varscan2
- LRRN2 | c.2141G>T p.*714Lext*8 | Nonstop Mutation (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- NRCAM | c.3190C>A p.Q1064K | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS54 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPL38 | c.67G>T p.V23F | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, varscan2
- SLC24A2 | c.1759T>G p.Y587D | Missense Mutation (SNP) | VAF 6/159 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TNPO1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF573 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FREM3 | c.834C>T p.D278= | Silent (SNP) | VAF 278/576 reads (48%) | called by muse, varscan2
- SLC26A3 | c.138C>T p.S46= | Silent (SNP) | VAF 109/216 reads (50%) | catalogued as rs750358656; called by muse, mutect2, varscan2
- TYRO3 | c.1336C>T p.L446= | Silent (SNP) | VAF 146/395 reads (37%) | called by muse, mutect2, varscan2
- FUT9 | c.*7911A>G | 3'UTR (SNP) | VAF 171/328 reads (52%) | catalogued as COSV100133553; called by muse, mutect2, varscan2
